MMRF case MMRF_2011 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c8a7dd97-2573-4c08-af5c-ae0c50674a52

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.7 years (26,913 days); ISS stage: III; Days to last known disease status: 990 days (2.7 years); Days to last follow up: 990 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 42 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 98 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 98 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 98 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 133 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 315 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 137 days; Days to treatment end: 227 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 239 days; Days to treatment end: 259 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 267 days; Days to treatment end: 280 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 281 days; Days to treatment end: 302 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 316 days; Days to treatment end: 429 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 316 days; Days to treatment end: 399 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 400 days (1.1 years); Days to treatment end: 429 days (1.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 444 days (1.2 years); Days to treatment end: 466 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 444 days (1.2 years); Days to treatment end: 464 days (1.3 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 661 days (1.8 years); Days to treatment end: 688 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 661 days (1.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 689 days (1.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1470 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.2 mg/dL; Immunoglobulin G 4.99 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 6.77 µg/mL; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 6.6 mmol/L; C-Reactive Protein 3.55 mg/dL.
- Day 99: Serum Free Immunoglobulin Light Chain, Kappa 893 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 3.48 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 7.2 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 63 ×10⁹/L; Creatinine 200 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 6.77 mmol/L.
- Day 197: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 65.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 3.5 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 176 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 7.15 mmol/L.
- Day 281: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 767 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 178 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 9.96 mmol/L.
- Day 372: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 80.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.29 mg/dL; Immunoglobulin G 2.38 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 4.35 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 214 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 5.5 g/dL; Glucose 8.47 mmol/L.
- Day 444: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.21 mg/dL; Immunoglobulin G 2.22 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.39 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 184 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 5.2 g/dL; Glucose 5.61 mmol/L.
- Day 547 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.33 mg/dL; Immunoglobulin G 2.79 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 305 µmol/L; Blood Urea Nitrogen 18.9 mmol/L; Calcium 2.28 mmol/L; Total Protein 5.4 g/dL; Glucose 10.5 mmol/L.
- Day 627: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 74.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.01 mg/dL; Immunoglobulin G 2.89 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 71 ×10⁹/L; Creatinine 316 µmol/L; Blood Urea Nitrogen 19.3 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 5.6 g/dL; Glucose 5.17 mmol/L.
- Day 731 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 2.15 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 7.79 µg/mL; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 238 µmol/L; Blood Urea Nitrogen 24.3 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 5.3 g/dL; Glucose 4.07 mmol/L.
- Day 815 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 1.74 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 6.34 µg/mL; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.89 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 255 µmol/L; Blood Urea Nitrogen 25.3 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 5.5 g/dL; Glucose 8.31 mmol/L.
- Day 906: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 30.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 2.2 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 7.46 µg/mL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 260 µmol/L; Blood Urea Nitrogen 20.3 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 5.4 g/dL; Glucose 5.67 mmol/L.
- Day 990: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 3.19 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 7.02 µg/mL; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 246 µmol/L; Blood Urea Nitrogen 26.8 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 5.6 g/dL; Glucose 19.4 mmol/L.

Other clinical attributes
- Day 1: Weight: 110 kg; Height: 164 cm.

Biospecimens (2 samples)
- Sample MMRF_2011_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 281 days.
- Sample MMRF_2011_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 281 days.
